Somatic mutation profile of tumor specimen TCGA-S5-A6DX-01A (aliquot TCGA-S5-A6DX-01A-11D-A31L-08) from TCGA case TCGA-S5-A6DX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 83.8 years (30,594 days).
Specimen TCGA-S5-A6DX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 957b4188-8e07-479c-ad66-14efb0bfb569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S5-A6DX-10A (Blood Derived Normal), aliquot TCGA-S5-A6DX-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8e73c42-961e-4467-a678-0cb2f4e8ae19

The open-access MAF lists 762 somatic variants for this specimen: 542 protein-altering or splice-affecting, 193 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 474, Silent 193, Nonsense Mutation 48, Intron 14, Splice Site 10, Frame Shift Del 5, 5'Flank 4, 5'UTR 3, 3'UTR 3, Splice Region 2, Translation Start Site 2, RNA 2.

Variants (750 of 762; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAB21L2 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777514, CM145907, COSV58261294; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.3964G>A p.D1322N | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs771665597, COSV60914657; called by muse, mutect2, varscan2
- AC004922.1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.048); catalogued as rs779413485, COSV53163063; called by muse, mutect2, varscan2
- ACOT12 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV56895518; called by muse, mutect2, varscan2
- ACTN4 | c.2341C>T p.H781Y | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs952714063, COSV53147124; called by muse, mutect2, varscan2
- ACVRL1 | c.1415G>A p.W472* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as rs1555154144, COSV101187944; called by muse, mutect2, varscan2
- ADAM12 | c.2388G>C p.Q796H | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV64130941, COSV64132931; called by muse, mutect2, varscan2
- ADSL | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV53408215; called by muse, varscan2
- ADSS2 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV63695372; called by muse, mutect2, varscan2
- AFF3 | c.2113G>C p.D705H | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV57857475; called by muse, mutect2, varscan2
- AFTPH | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1280487180, COSV53218947; called by muse, mutect2, varscan2
- AGTPBP1 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100429789, COSV61272827; called by muse, mutect2, varscan2
- AJAP1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.84); catalogued as COSV65451301; called by muse, varscan2
- AKAP5 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 100/222 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV57742584; called by muse, mutect2, varscan2
- AKAP9 | c.5914G>C p.E1972Q (on ENST00000359028; = p.E1940Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/240 reads (22%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.942); catalogued as COSV62349030; called by muse, mutect2, varscan2
- AKT1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV62573987; called by muse, mutect2, varscan2
- ALK | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs771593278, COSV66572608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMN1 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV55671875; called by muse, mutect2, varscan2
- ANKRD11 | c.4891C>T p.R1631W | Missense Mutation (SNP) | VAF 80/247 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1402377065, COSV56363112; called by muse, mutect2, varscan2
- ANKRD35 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.033); catalogued as COSV62910672; called by muse, mutect2, varscan2
- ANKS1A | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV64461568; called by muse, mutect2, varscan2
- ANXA5 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374862609; called by muse, mutect2, varscan2
- AOAH | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.214); catalogued as COSV51743360; called by muse, mutect2, varscan2
- AP3B2 | c.2599G>T p.E867* (on ENST00000261722; = p.E861* on NM_004644.5) | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99916602; called by muse, mutect2, varscan2
- APOA2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs146224429; called by muse, mutect2, varscan2
- ARFGEF2 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 85/334 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.63); catalogued as COSV64212933; called by muse, mutect2, varscan2
- ARHGAP33 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as rs1027735867, COSV50126627; called by muse, mutect2, varscan2
- ARHGAP9 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 35/160 reads (22%) | catalogued as rs760103624, COSV57364355; called by muse, mutect2, varscan2
- ARHGEF12 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63105420; called by muse, mutect2, varscan2
- ARHGEF25 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.262); catalogued as COSV54087379; called by muse, mutect2, varscan2
- ARHGEF25 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.351); catalogued as COSV54087401, COSV99678340; called by muse, mutect2, varscan2
- ARHGEF4 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs770753604, COSV58123831; called by muse, mutect2, varscan2
- ARID3C | c.614G>C p.R205P | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs1252466141, COSV99426926; called by muse, mutect2
- ARIH1 | c.559C>G p.Q187E | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65911915; called by muse, mutect2, varscan2
- ASB11 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV60355515; called by muse, mutect2, varscan2
- ASF1A | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 88/242 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV57647961, COSV57648054; called by muse, mutect2, varscan2
- ASH1L | c.6433C>T p.Q2145* (on ENST00000368346 / NM_001366177.2; = p.Q2140* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 17/148 reads (11%) | catalogued as COSV100853472; called by muse, mutect2, varscan2
- ASH1L | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV64208103, COSV64209181; called by muse, mutect2, varscan2
- ASH1L | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.001); catalogued as rs373475579; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASNSD1 | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV53623948; called by muse, mutect2, varscan2
- ATF7IP | c.1063G>C p.D355H | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.017); catalogued as COSV53772452; called by muse, mutect2, varscan2
- ATF7IP | c.1297G>C p.D433H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53772472; called by muse, mutect2, varscan2
- ATF7IP | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as COSV53770183; called by muse, mutect2, varscan2
- ATG4C | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 17/114 reads (15%) | catalogued as rs771869494, COSV100508277; called by muse, mutect2, varscan2
- ATP11A | c.2720C>G p.S907* | Nonsense Mutation (SNP) | VAF 58/167 reads (35%) | catalogued as COSV99368875; called by muse, mutect2, varscan2
- ATP2B4 | c.2779C>G p.Q927E | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58179150; called by muse, mutect2, varscan2
- ATP8A1 | c.771G>C p.L257F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52537870; called by muse, mutect2, varscan2
- ATP8B1 | c.2383G>A p.G795R | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV52176789; called by muse, varscan2
- ATP8B1 | c.2324G>C p.R775T | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs746969851, COSV52176801; called by muse, varscan2
- AUTS2 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 76/297 reads (26%) | catalogued as COSV100717773; called by muse, mutect2, varscan2
- BAIAP2 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.918); catalogued as COSV58336461; called by muse, mutect2, varscan2
- BANP | c.1489-1G>A p.X497_splice (on ENST00000286122; = p.X447_splice on NM_017869.4) | Splice Site (SNP) | VAF 10/56 reads (18%) | catalogued as COSV53739021; called by muse, mutect2, varscan2
- BCL11A | c.7C>G p.R3G | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV59632474; called by muse, mutect2, varscan2
- BLNK | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV56411838; called by muse, mutect2, varscan2
- BMP8B | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249066960, COSV62927953; called by muse, mutect2, varscan2
- BOP1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs782512248, COSV56639614; called by muse, mutect2, varscan2
- BRD9 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV60247160; called by muse, mutect2, varscan2
- BZW2 | c.671G>C p.R224T | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV51755619; called by muse, mutect2, varscan2
- C18orf32 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV59087782; called by muse, mutect2, varscan2
- C1QL1 | c.696C>G p.I232M | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53647502; called by muse, mutect2, varscan2
- C4orf19 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV52649442, COSV52649547; called by muse, mutect2, varscan2
- C7orf50 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV62475699; called by muse, mutect2, varscan2
- C8orf76 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.113); catalogued as COSV104372585, COSV52690776; called by muse, mutect2, varscan2
- C9orf40 | c.200C>A p.S67* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100964975, COSV100964989; called by muse, mutect2, varscan2
- CA2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53405751; called by muse, mutect2, varscan2
- CA5A | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV59241329; called by muse, mutect2, varscan2
- CACNA1H | c.3137G>C p.R1046T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV61993425; called by muse, mutect2, varscan2
- CACNA2D1 | c.460A>G p.N154D | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV62381979; called by muse, mutect2, varscan2
- CADPS | c.2009C>G p.S670C | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1472586855, COSV51882177; called by muse, mutect2, varscan2
- CAND1 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV73338896; called by muse, mutect2, varscan2
- CAPN9 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55234990, COSV99680522; called by muse, mutect2, varscan2
- CAT | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.695); catalogued as COSV53810895; called by muse, mutect2, varscan2
- CBR3 | c.177C>A p.F59L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV51741507; called by muse, mutect2, varscan2
- CCDC171 | c.2139C>G p.F713L | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52639583, COSV52643745; called by muse, mutect2, varscan2
- CCDC18 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58144442; called by muse, mutect2, varscan2
- CCDC189 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV60312522; called by muse, mutect2, varscan2
- CCDC28A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs760669204, COSV60425229; called by muse, mutect2, varscan2
- CCDC87 | c.537C>G p.F179L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.513); catalogued as COSV59579376; called by muse, mutect2, varscan2
- CDC5L | c.1189C>G p.P397A | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV65176379; called by muse, varscan2
- CDC7 | c.956G>A p.R319K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV52311088, COSV99319675; called by muse, mutect2, varscan2
- CDK5R1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV55579315; called by muse, varscan2
- CDKN1A | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs753291170, COSV55186640, COSV55189397; called by muse, mutect2, varscan2
- CDO1 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 90/351 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV51665522; called by muse, mutect2, varscan2
- CECR2 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52843224; called by muse, mutect2, varscan2
- CECR2 | c.3022G>A p.D1008N (on ENST00000342247 / NM_001290047.2; = p.D824N on NM_001290046.1) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV52843252; called by muse, mutect2, varscan2
- CECR2 | c.3235G>A p.G1079R (on ENST00000342247 / NM_001290047.2; = p.G895R on NM_001290046.1) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV52843270; called by muse, mutect2, varscan2
- CENPE | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54382834; called by muse, mutect2, varscan2
- CEP152 | c.3328G>A p.D1110N | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV57860471; called by muse, mutect2, varscan2
- CFAP54 | c.6922C>T p.Q2308* | Nonsense Mutation (SNP) | VAF 3/8 reads (38%) | catalogued as COSV100733233; called by muse, mutect2
- CFAP65 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs760496355, COSV58562117; called by muse, mutect2, varscan2
- CFAP70 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60284009; called by muse, mutect2, varscan2
- CHAD | c.893C>T p.T298I | Missense Mutation (SNP) | VAF 86/335 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV51972969; called by muse, mutect2, varscan2
- CHRNA2 | c.810C>G p.I270M | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs892421066, COSV53556732, COSV53558165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIDEB | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV51866316; called by muse, mutect2, varscan2
- CLIC5 | c.1183G>C p.E395Q (on ENST00000185206 / NM_001370649.1; = p.E236Q on NM_016929.5) | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757089924, COSV51760102; called by muse, mutect2, varscan2
- CLIC5 | c.742G>C p.E248Q (on ENST00000185206 / NM_001370649.1; = p.E89Q on NM_016929.5) | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51760117; called by muse, mutect2, varscan2
- CNOT3 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55364524; called by muse, mutect2, varscan2
- CNTN4 | c.902G>C p.R301T | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV61874876; called by muse, mutect2, varscan2
- COL12A1 | c.401C>A p.S134Y | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.996); catalogued as COSV59398170; called by muse, mutect2, varscan2
- COL6A3 | c.9461C>T p.S3154L | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV55093781; called by muse, mutect2, varscan2
- COL6A3 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs759280111, COSV55093795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPS4 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52315646; called by muse, mutect2, varscan2
- COQ10B | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs938803665, COSV55836516; called by muse, mutect2, varscan2
- COQ9 | c.522-2A>G p.X174_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as COSV52646141; called by muse, mutect2, varscan2
- CPOX | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV51638800; called by muse, mutect2, varscan2
- CPTP | c.645G>C p.*215Yext*44 | Nonstop Mutation (SNP) | VAF 35/139 reads (25%) | catalogued as COSV59563694; called by muse, mutect2, varscan2
- CRISPLD2 | c.836C>G p.S279C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV52280286, COSV52283096; called by muse, varscan2
- CRYBG1 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 101/258 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as COSV64812715; called by muse, mutect2, varscan2
- CSF1R | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV53836580; called by muse, mutect2, varscan2
- CTDSP1 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1290860750, COSV51917603; called by muse, mutect2, varscan2
- CTDSPL2 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52946652; called by muse, mutect2, varscan2
- CYB5R3 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.687); catalogued as rs142587038; called by muse, mutect2, varscan2
- CYP26A1 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV56418753; called by muse, mutect2, varscan2
- CYP27A1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1046723537, CD119151, COSV51468634; called by muse, varscan2
- CYP27A1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51468649; called by muse, varscan2
- DBN1 | c.1093C>G p.P365A | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV52788555, COSV52790187; called by muse, varscan2
- DCST1 | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55060162; called by muse, mutect2, varscan2
- DCUN1D2 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV60261549; called by muse, mutect2, varscan2
- DDB1 | c.1836C>G p.F612L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs1401595145, COSV57103611; called by muse, mutect2, varscan2
- DDC | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as COSV63565682; called by muse, varscan2
- DDC | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV63565688; called by muse, varscan2
- DDX24 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs535305749, COSV58212801; called by muse, mutect2, varscan2
- DENND5A | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60234694; called by muse, mutect2, varscan2
- DHX8 | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs1185324387, COSV52254008, COSV52256874, COSV99292090; called by muse, mutect2, varscan2
- DIS3L | c.2047G>A p.E683K (on ENST00000319212 / NM_001143688.3; = p.E600K on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59912714; called by muse, mutect2, varscan2
- DKKL1 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1438942073, COSV55562683; called by muse, mutect2, varscan2
- DLD | c.16C>G p.R6G | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.14); catalogued as COSV52738412; called by muse, mutect2, varscan2
- DMBX1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs760474949, COSV63601963; called by muse, mutect2, varscan2
- DNAH11 | c.2825C>T p.P942L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1036851692, COSV60960965; called by muse, varscan2
- DNAH9 | c.12650G>A p.R4217K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1253167875, COSV52355203; called by muse, mutect2, varscan2
- DPP3 | c.1160C>G p.P387R | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64757045; called by muse, mutect2, varscan2
- DPP8 | c.2067G>C p.L689F (on ENST00000341861 / NM_001320875.2; = p.L673F on NM_130434.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV55679753; called by muse, mutect2, varscan2
- DTWD1 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV52071965; called by muse, mutect2, varscan2
- DYRK1A | c.1720C>G p.P574A | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as rs768231661, COSV58703999, COSV58707033; called by muse, mutect2, varscan2
- ECSIT | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766931733, COSV52939768; called by muse, mutect2, varscan2
- EDC3 | c.413C>G p.S138* | Nonsense Mutation (SNP) | VAF 47/209 reads (22%) | catalogued as COSV100166017; called by muse, mutect2, varscan2
- EDDM3B | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528414264, COSV58747165; called by muse, mutect2, varscan2
- EFCAB6 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.235); catalogued as COSV53065320; called by muse, mutect2, varscan2
- EIF2AK3 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV57548629; called by muse, mutect2, varscan2
- ELP4 | c.967G>C p.D323H (on ENST00000350638; = p.D322H on NM_019040.5) | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100635887, COSV63353770, COSV63356244; called by muse, mutect2, varscan2
- EME1 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs747603787, COSV56812685; called by muse, mutect2, varscan2
- EMILIN1 | c.1472C>G p.S491C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV53155302; called by muse, mutect2, varscan2
- EPG5 | c.6664C>G p.Q2222E | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV56351148; called by muse, mutect2, varscan2
- EPHA5 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs749830045, COSV56645016; called by muse, mutect2, varscan2
- EPHB3 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57806807; called by muse, mutect2, varscan2
- ERCC8 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV54016314; called by muse, mutect2, varscan2
- ERV3-1 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV51428193; called by muse, mutect2, varscan2
- ESS2 | c.246G>C p.Q82H | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs569930086, COSV52817286; called by muse, mutect2, varscan2
- ESYT2 | c.2273C>T p.S758L (on ENST00000613624; = p.S682L on NM_020728.3) | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51747930; called by muse, mutect2, varscan2
- ETV4 | c.1230G>A p.K410= | Splice Region (SNP) | VAF 103/347 reads (30%) | catalogued as COSV52254013; called by muse, mutect2, varscan2
- ETV7 | c.305C>G p.S102* | Nonsense Mutation (SNP) | VAF 31/235 reads (13%) | catalogued as COSV60318416; called by muse, mutect2, varscan2
- F13B | c.964A>G p.T322A | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV66374342; called by muse, mutect2, varscan2
- FABP6 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1223055999, COSV67437165; called by muse, mutect2, varscan2
- FAM133A | c.218T>A p.L73H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV59076061; called by muse, mutect2, varscan2
- FAM214A | c.1143G>C p.L381F | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55924980; called by muse, varscan2
- FAM214A | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV55922563; called by muse, varscan2
- FAM214A | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); catalogued as COSV55924994; called by muse, mutect2, varscan2
- FAM214A | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55922915, COSV55925007; called by muse, varscan2
- FAM214A | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV55925017; called by muse, varscan2
- FAM217A | c.865C>A p.R289S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51159197, COSV51160567; called by muse, mutect2, varscan2
- FARSB | c.728G>C p.R243T | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV56050245, COSV99918077; called by muse, mutect2, varscan2
- FAT3 | c.6559G>C p.D2187H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53125259; called by muse, mutect2, varscan2
- FAT3 | c.8634G>C p.L2878F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99967062; called by muse, mutect2
- FBN3 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV54453189; called by muse, mutect2, varscan2
- FBXL19 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.885); catalogued as COSV57943150; called by muse, mutect2, varscan2
- FBXL3 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV62918873; called by muse, mutect2, varscan2
- FBXO38 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.134); catalogued as rs746327159, COSV57028688; called by muse, mutect2, varscan2
- FCRL3 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as COSV63842416; called by muse, mutect2, varscan2
- FCRL6 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as rs148840420; called by muse, mutect2, varscan2
- FCSK | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV55371511; called by mutect2, varscan2
- FERMT3 | c.1300G>C p.E434Q (on ENST00000279227 / NM_178443.3; = p.E430Q on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 153/488 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV54180816, COSV54183412; called by muse, mutect2, varscan2
- FGD1 | c.2762G>A p.R921Q | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.498); catalogued as rs368175921, COSV64308924; called by muse, mutect2, varscan2
- FGF5 | c.794T>G p.F265C | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV56890526; called by muse, mutect2, varscan2
- FH | c.1253A>T p.H418L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV63818325; called by muse, mutect2
- FLAD1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV52695918, COSV52696358, COSV99422625; called by muse, mutect2, varscan2
- FLG | c.8713G>A p.E2905K | Missense Mutation (SNP) | VAF 150/785 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV64243100, COSV64244907; called by muse, mutect2, varscan2
- FLG2 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 91/514 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.234); catalogued as COSV66169486; called by muse, mutect2, varscan2
- FLRT1 | c.1744G>T p.E582* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV55360763, COSV99735423; called by muse, mutect2, varscan2
- FLRT2 | c.23G>A p.W8* | Nonsense Mutation (SNP) | VAF 45/120 reads (38%) | catalogued as COSV100420543, COSV58141352; called by muse, mutect2, varscan2
- FOXK2 | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV58879792; called by muse, mutect2, varscan2
- FOXP2 | c.1669A>T p.S557C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV63486122, COSV63487940; called by muse, mutect2, varscan2
- FRY | c.7498G>C p.E2500Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.083); catalogued as COSV66572088; called by muse, mutect2, varscan2
- FSD2 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs1257916764, COSV58010684; called by muse, mutect2, varscan2
- FUT4 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2
- FXR1 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs746038547, COSV59762458; called by muse, mutect2, varscan2
- FXR2 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51518262; called by muse, mutect2, varscan2
- FXYD5 | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV61568987; called by muse, mutect2, varscan2
- FZD2 | c.1611C>G p.F537L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); catalogued as COSV59529287; called by muse, mutect2, varscan2
- FZD5 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54943826; called by muse, mutect2, varscan2
- GABRB3 | c.20G>C p.G7A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.007); catalogued as COSV100160347; called by muse, varscan2
- GLI1 | c.1837G>C p.G613R | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57363523, COSV57367752; called by muse, mutect2, varscan2
- GLO1 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV64905287; called by muse, varscan2
- GLYATL1 | c.196G>T p.D66Y (on ENST00000317391 / NM_001354699.1; = p.D97Y on NM_080661.4) | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55609451; called by muse, mutect2, varscan2
- GNB4 | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51709974; called by muse, mutect2, varscan2
- GPATCH8 | c.1244G>C p.R415T | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV59195481; called by muse, mutect2, varscan2
- GPC6 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV65515372; called by muse, mutect2, varscan2
- GPR89B | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100032512; called by mutect2, varscan2
- GTSE1 | c.774G>C p.E258D | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.331); catalogued as COSV71889235; called by muse, mutect2, varscan2
- H3C4 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV61911531, COSV61912198, COSV61912262; called by muse, mutect2, varscan2
- HACL1 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs766609037, COSV58254948; called by muse, mutect2, varscan2
- HAUS3 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54723015; called by muse, mutect2, varscan2
- HERC2 | c.13927G>C p.D4643H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55328671; called by muse, mutect2, varscan2
- HERC5 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as rs1206625081, COSV52040881; called by muse, mutect2, varscan2
- HES1 | c.777C>A p.N259K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.095); catalogued as COSV51684894; called by muse, mutect2, varscan2
- HIVEP2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV50018491; called by muse, mutect2, varscan2
- HIVEP3 | c.5975C>T p.S1992L | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56017075; called by muse, mutect2, varscan2
- HIVEP3 | c.5701C>T p.Q1901* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99912960; called by muse, mutect2, varscan2
- HLA-DPA1 | c.45G>C p.L15F | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV69822703; called by muse, mutect2, varscan2
- HMG20A | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60312959; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.259G>C p.D87H (on ENST00000354667 / NM_031243.3; = p.D75H on NM_002137.4) | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61159727; called by muse, mutect2, varscan2
- HNRNPH1 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as COSV61486774; called by muse, mutect2, varscan2
- HOXB6 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV53313362; called by muse, mutect2
- HPCAL1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); catalogued as COSV57146853; called by muse, mutect2, varscan2
- HPSE2 | c.893G>C p.R298T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as COSV65191717; called by muse, mutect2, varscan2
- ID1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 25/100 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as COSV65888658; called by muse, mutect2, varscan2
- IDH2 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57468821; called by muse, mutect2, varscan2
- IFNA16 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 114/338 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV66510163; called by muse, varscan2
- IKZF2 | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV59578243; called by muse, mutect2, varscan2
- IL17RA | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV60054113; called by muse, mutect2, varscan2
- IL1R2 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs759636734, COSV60206891; called by muse, mutect2, varscan2
- IL20 | c.78G>C p.K26N | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV65584674; called by muse, mutect2, varscan2
- ING5 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57978204; called by muse, mutect2, varscan2
- INTS11 | c.915C>G p.I305M | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV60088859; called by muse, mutect2, varscan2
- IQGAP2 | c.4405G>C p.E1469Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as COSV57175441; called by muse, mutect2, varscan2
- IRX5 | c.1310C>G p.S437C | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV58059166; called by muse, mutect2, varscan2
- ITGAL | c.2293-1G>T p.X765_splice | Splice Site (SNP) | VAF 39/230 reads (17%) | catalogued as COSV63322692, COSV63324413; called by muse, mutect2, varscan2
- JPH1 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV60611963; called by muse, mutect2, varscan2
- JPH3 | c.1403C>G p.S468C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV52468925; called by muse, mutect2, varscan2
- KARS1 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV56692739; called by muse, mutect2, varscan2
- KCNK15 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV100865138; called by muse, varscan2
- KCTD20 | c.469C>G p.R157G | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54803591; called by muse, mutect2, varscan2
- KDM2B | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65641988, COSV65644337; called by muse, mutect2, varscan2
- KDM3B | c.3208G>C p.E1070Q | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV58691729; called by muse, mutect2, varscan2
- KIAA1522 | c.1525del p.R509Gfs*84 (on ENST00000373480 / NM_001198972.2; = p.R568Gfs*84 on NM_020888.3) | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as COSV53867914; called by mutect2, pindel, varscan2
- KIF11 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53271316; called by muse, mutect2
- KIF17 | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV56119181; called by muse, mutect2, varscan2
- KIF4A | c.1758G>C p.K586N | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV65543961; called by muse, mutect2, varscan2
- KIFBP | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.026); catalogued as rs121434515, CM051942, COSV62555841; called by muse, mutect2, varscan2
- KIN | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59621992; called by muse, mutect2, varscan2
- KIR3DL1 | c.122G>C p.R41P | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV58492233; called by muse, mutect2, varscan2
- KLF5 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV66614445, COSV66614565; called by muse, mutect2, varscan2
- KLHL15 | c.1419G>C p.K473N | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.432); catalogued as COSV60140694; called by muse, mutect2, varscan2
- KLHL15 | c.1160G>C p.R387T | Missense Mutation (SNP) | VAF 71/125 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV60140704, COSV60141423; called by muse, mutect2, varscan2
- KLHL34 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.061); catalogued as COSV65278967; called by mutect2, varscan2
- KLHL9 | c.1850C>G p.S617C | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV62921861; called by muse, mutect2, varscan2
- KMT2D | c.15202G>A p.E5068K | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV56451763; called by muse, mutect2, varscan2
- KRT31 | c.1083G>C p.E361D | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as COSV52435815; called by muse, mutect2, varscan2
- KRT8 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 20/111 reads (18%) | catalogued as rs141850020; called by muse, varscan2
- KRTAP10-6 | c.635C>G p.S212C | Missense Mutation (SNP) | VAF 113/335 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1173333113, COSV59966602; called by muse, mutect2, varscan2
- KRTAP9-4 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 100/324 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.9); catalogued as COSV61898188; called by muse, mutect2, varscan2
- LAMA2 | c.6997C>T p.Q2333* | Nonsense Mutation (SNP) | VAF 43/127 reads (34%) | catalogued as COSV101370555; called by muse, mutect2, varscan2
- LAMTOR5 | c.272C>G p.S91C (on ENST00000602318 / NM_001382293.1; = p.S173C on NM_006402.3) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56679075; called by muse, mutect2, varscan2
- LCE1C | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 59/173 reads (34%) | catalogued as COSV100908449; called by muse, mutect2, varscan2
- LEMD3 | c.2663C>G p.S888* | Nonsense Mutation (SNP) | VAF 38/284 reads (13%) | catalogued as COSV100384382; called by muse, mutect2, varscan2
- LHX1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs150197430; called by muse, mutect2, varscan2
- LILRB3 | c.1724C>G p.S575C (on ENST00000346401; = p.S563C on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54427807; called by muse, mutect2, varscan2
- LRAT | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60477327; called by muse, mutect2, varscan2
- LRFN2 | c.1940C>T p.P647L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs776997956, COSV57828761; called by muse, mutect2, varscan2
- LRP1 | c.10545C>A p.D3515E | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54511293, COSV54514753; called by muse, mutect2, varscan2
- LRRN2 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV65784076; called by muse, mutect2, varscan2
- LRRN3 | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as COSV57820852; called by muse, mutect2, varscan2
- LTB | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.23); catalogued as rs1275218202, COSV101438053; called by muse, mutect2
- LUZP1 | c.1378T>C p.S460P | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV56502288; called by mutect2, varscan2
- LYST | c.7470G>A p.M2490I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67708243; called by muse, mutect2, varscan2
- MAD2L1BP | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as rs745519010, COSV64665114; called by muse, mutect2, varscan2
- MAEL | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63304964, COSV63305414; called by muse, mutect2, varscan2
- MAN2B2 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV53453817; called by muse, mutect2, varscan2
- MAP1S | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60723118; called by muse, mutect2
- MAP4K3 | c.1377C>G p.I459M | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV55714276; called by muse, mutect2, varscan2
- MASTL | c.471G>C p.L157F | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60911220; called by muse, mutect2, varscan2
- MATN2 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as rs755621628, COSV54713015; called by muse, mutect2, varscan2
- MBD4 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1365312836, COSV51444874; called by muse, mutect2, varscan2
- MCM6 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.088); catalogued as COSV51467099; called by muse, varscan2
- MCPH1 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV60914851; called by muse, mutect2, varscan2
- MCUR1 | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV64846949; called by muse, mutect2, varscan2
- MEFV | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as CM014957, COSV54823262; called by muse, mutect2, varscan2
- MFSD11 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs763350082, COSV60620942; called by muse, mutect2, varscan2
- MINAR1 | c.968A>G p.K323R | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV59583754; called by muse, mutect2, varscan2
- MLF1 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as rs141212572; called by muse, mutect2, varscan2
- MLIP | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV51430553; called by muse, mutect2, varscan2
- MLPH | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV52821314; called by muse, mutect2
- MPL | c.1492C>G p.L498V | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV65245211; called by muse, mutect2, varscan2
- MRGBP | c.148+1G>A p.X50_splice | Splice Site (SNP) | VAF 9/11 reads (82%) | catalogued as COSV100978286; called by muse, mutect2, varscan2
- MRPS9 | c.136A>C p.I46L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV51520137; called by muse, mutect2, varscan2
- MS4A3 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1359953700, COSV53936606; called by muse, varscan2
- MS4A3 | c.132G>C p.Q44H | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.667); catalogued as COSV53935608, COSV53936618; called by muse, varscan2
- MSS51 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV55019529, COSV55020483; called by muse, mutect2, varscan2
- MTHFD2L | c.505G>A p.D169N (on ENST00000395759 / NM_001144978.2; = p.D111N on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57467992, COSV57471225; called by muse, varscan2
- MUC16 | c.24197C>G p.S8066C | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as COSV67473295; called by muse, mutect2, varscan2
- MUC16 | c.23626C>G p.Q7876E | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs759110145, COSV67473303; called by muse, mutect2, varscan2
- MUC16 | c.23415T>A p.D7805E | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.006); catalogued as COSV67473311; called by muse, mutect2, varscan2
- MUC16 | c.16435A>G p.T5479A | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV67473316; called by muse, mutect2, varscan2
- MUC4 | c.12743C>T p.S4248L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.316); catalogued as rs766190178, COSV57785742; called by muse, mutect2, varscan2
- MYCBP2 | c.6871C>G p.Q2291E (on ENST00000357337; = p.Q2329E on NM_015057.5) | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV62023602; called by muse, mutect2, varscan2
- MYCBP2 | c.1207G>A p.E403K (on ENST00000357337; = p.E441K on NM_015057.5) | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV62023627; called by muse, mutect2, varscan2
- MYCBPAP | c.1916C>G p.S639C | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV60408741; called by muse, mutect2, varscan2
- MYH15 | c.5092G>A p.E1698K | Missense Mutation (SNP) | VAF 114/430 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV56312214; called by muse, mutect2, varscan2
- MYH8 | c.4538C>G p.S1513C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV67966914; called by muse, mutect2, varscan2
- MYLIP | c.557G>A p.G186D | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62766943; called by muse, mutect2, varscan2
- MYO15A | c.7221G>C p.E2407D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV52758553, COSV99233199; called by muse, mutect2, varscan2
- MYO1A | c.2885C>T p.S962L | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.094); catalogued as rs772899759, COSV55654779; called by muse, mutect2, varscan2
- MYO1H | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.273); catalogued as COSV60446811; called by muse, mutect2, varscan2
- MYO7B | c.3727G>A p.A1243T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs182704605, COSV67348625; called by muse, mutect2, varscan2
- NAA25 | c.2236G>C p.E746Q | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); catalogued as COSV55705163; called by muse, mutect2, varscan2
- NAPRT | c.1291+1G>C p.X431_splice | Splice Site (SNP) | VAF 74/169 reads (44%) | catalogued as COSV52786175; called by muse, mutect2, varscan2
- NAV1 | c.5539-1G>C p.X1847_splice | Splice Site (SNP) | VAF 6/55 reads (11%) | catalogued as COSV55219312; called by muse, mutect2, varscan2
- NCOA3 | c.4124C>G p.S1375C (on ENST00000371998 / NM_181659.3; = p.S1371C on NM_006534.4) | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV100507822, COSV59069754; called by muse, mutect2, varscan2
- NCOA3 | c.4261C>T p.Q1421* (on ENST00000371998 / NM_181659.3; = p.Q1417* on NM_006534.4) | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as rs199588007, COSV100507686; called by muse, mutect2, varscan2
- NCSTN | c.1654C>T p.Q552* | Nonsense Mutation (SNP) | VAF 114/342 reads (33%) | catalogued as COSV99667255; called by muse, mutect2, varscan2
- NDUFAF1 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV52975626; called by muse, mutect2, varscan2
- NEB | c.7330G>A p.E2444K | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51426157; called by muse, mutect2, varscan2
- NES | c.1076C>A p.P359H | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV63961410; called by muse, mutect2, varscan2
- NEU4 | c.1389C>A p.N463K (on ENST00000391969 / NM_001167602.3; = p.N475K on NM_080741.4) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57990753; called by muse, mutect2, varscan2
- NINJ2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV56753561, COSV99842544; called by muse, mutect2, varscan2
- NOL11 | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 41/158 reads (26%) | catalogued as COSV99475104; called by muse, mutect2, varscan2
- NOP14 | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58625858; called by muse, mutect2, varscan2
- NOTCH4 | c.4190C>T p.P1397L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as rs753178549, COSV100900675, COSV66681461; called by muse, mutect2, varscan2
- NPC1 | c.3478-1G>C p.X1160_splice | Splice Site (SNP) | VAF 6/37 reads (16%) | catalogued as COSV52572445, COSV99340362; called by muse, varscan2
- NRDC | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV61405400; called by muse, mutect2, varscan2
- NT5E | c.1195G>C p.D399H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV57628823; called by muse, mutect2, varscan2
- NUAK2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs199544834, COSV65681729; called by muse, mutect2, varscan2
- NUP205 | c.5714G>C p.W1905S | Missense Mutation (SNP) | VAF 66/308 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53660787; called by muse, varscan2
- OAS3 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57446506; called by muse, mutect2, varscan2
- OBI1 | c.1259C>G p.S420* | Nonsense Mutation (SNP) | VAF 45/132 reads (34%) | catalogued as COSV99932513; called by muse, mutect2, varscan2
- OBSCN | c.8873C>T p.S2958L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs973888849, COSV52784851, COSV99483230; called by muse, mutect2, varscan2
- OGDH | c.2091G>C p.K697N | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV56051820; called by muse, mutect2, varscan2
- OGDH | c.2815G>A p.D939N | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV56051835; called by muse, mutect2, varscan2
- OLFM2 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.174); catalogued as COSV53431277; called by muse, mutect2, varscan2
- OPA1 | c.802G>C p.E268Q (on ENST00000361510 / NM_130837.3; = p.E213Q on NM_015560.3) | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV62480024, COSV62481331; called by muse, mutect2, varscan2
- OR2A7 | c.914G>C p.G305A | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV101512221; called by muse, mutect2
- OR4K2 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 59/570 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs532614465, COSV100064681, COSV53849963; called by muse, mutect2, varscan2
- OR8H1 | c.491G>C p.R164T | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV57293805, COSV57294512; called by muse, mutect2, varscan2
- OSBPL8 | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 19/94 reads (20%) | catalogued as COSV99675170; called by muse, mutect2, varscan2
- OTX2 | c.349C>T p.P117S (on ENST00000408990 / NM_172337.3; = p.P125S on NM_021728.4) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as rs760396081, COSV59766535; called by muse, mutect2, varscan2
- PAPOLB | c.1496C>A p.P499H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV68201642; called by muse, mutect2, varscan2
- PARD3 | c.148C>G p.R50G | Missense Mutation (SNP) | VAF 47/353 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV60747993, COSV60749082; called by muse, mutect2, varscan2
- PCCB | c.804G>C p.L268F | Missense Mutation (SNP) | VAF 80/369 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs200865436, COSV52445785; called by muse, mutect2, varscan2
- PCDH9 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100118193, COSV60559484; called by muse, mutect2, varscan2
- PCDHA4 | c.426C>G p.I142M | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.957); catalogued as COSV63542718; called by muse, mutect2, varscan2
- PCDHB8 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.04); catalogued as COSV50761782; called by muse, mutect2, varscan2
- PCDHGA10 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.344); catalogued as COSV53966962, COSV54011010; called by muse, mutect2, varscan2
- PCDHGA6 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs200515281; called by muse, mutect2, varscan2
- PCP2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.288); catalogued as COSV60697426; called by muse, varscan2
- PCSK5 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 118/307 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1342727030, COSV65088660, COSV65090569; called by muse, mutect2, varscan2
- PGD | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV54621852; called by muse, mutect2, varscan2
- PHF3 | c.3322C>T p.Q1108* | Nonsense Mutation (SNP) | VAF 25/91 reads (27%) | catalogued as COSV100013465; called by muse, mutect2, varscan2
- PIAS3 | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV65171538; called by muse, mutect2, varscan2
- PIK3C2B | c.3916C>T p.Q1306* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100916154; called by muse, mutect2, varscan2
- PIK3C2B | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs373945378, COSV65812185; called by muse, varscan2
- PIK3C3 | c.2433-1G>A p.X811_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100010744, COSV100011074; called by muse, mutect2
- PJA1 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 118/190 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV64052706; called by muse, varscan2
- PJA1 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 54/96 reads (56%) | catalogued as COSV100824740; called by muse, varscan2
- PKHD1 | c.10813G>A p.E3605K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV64392402; called by muse, mutect2, varscan2
- PLAC9 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV64840581; called by muse, mutect2, varscan2
- PLCB2 | c.1797G>C p.Q599H | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53034541; called by muse, mutect2, varscan2
- PLEKHA4 | c.1716C>G p.H572Q | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV54363778; called by muse, mutect2, varscan2
- PLEKHA7 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV63047321; called by muse, mutect2, varscan2
- PLEKHG2 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); catalogued as rs770402704, COSV52685235; called by muse, mutect2, varscan2
- PLXNB1 | c.3805G>C p.E1269Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV56490884; called by muse, mutect2, varscan2
- PM20D1 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs200159366, COSV65649083; called by muse, mutect2, varscan2
- PNLDC1 | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 122/315 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV51706010; called by muse, mutect2, varscan2
- PNLIPRP2 | c.546G>C p.R182S | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.309); catalogued as COSV100077800; called by muse, mutect2
- POMGNT1 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | PolyPhen benign (0.014); catalogued as rs150351855; called by muse, mutect2, varscan2
- PPIP5K1 | c.4033G>C p.E1345Q (on ENST00000396923; = p.E1320Q on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV55809840; called by muse, mutect2, varscan2
- PPM1D | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59956256; called by muse, mutect2, varscan2
- PRAMEF12 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.162); catalogued as COSV63215614, COSV63216513; called by muse, varscan2
- PROSER1 | c.1159C>G p.R387G | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV61485926, COSV61488071; called by muse, mutect2, varscan2
- PRRT3 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55977529; called by muse, mutect2, varscan2
- PSG3 | c.854G>C p.R285T | Missense Mutation (SNP) | VAF 112/586 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.524); catalogued as COSV100549038; called by muse, mutect2, varscan2
- PSG8 | c.1216T>C p.S406P | Missense Mutation (SNP) | VAF 122/781 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV60612687; called by muse, mutect2, varscan2
- PSKH1 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV52123841, COSV99344970; called by muse, mutect2, varscan2
- PSME4 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV101122537; called by muse, mutect2
- PTCD2 | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.702); catalogued as COSV57338166; called by muse, mutect2, varscan2
- PTGER3 | c.1111T>A p.F371I (on ENST00000370932; = p.F371Y on NM_198716.2) | Missense Mutation (SNP) | VAF 114/382 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV63389671; called by muse, mutect2, varscan2
- PTGFRN | c.1943C>G p.S648* | Nonsense Mutation (SNP) | VAF 42/170 reads (25%) | catalogued as COSV101277391; called by muse, mutect2, varscan2
- PTPN9 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.325); catalogued as COSV60724187; called by muse, mutect2, varscan2
- PTPN9 | c.1000G>C p.G334R | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV60724195; called by muse, mutect2, varscan2
- PUS1 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs587781135, COSV59035736; called by muse, mutect2, varscan2
- PWWP2B | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59451201; called by muse, mutect2, varscan2
- QSOX2 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs376505854; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs1353082647, COSV50251254, COSV99242277; called by muse, mutect2, varscan2
- RAD50 | c.2055G>C p.Q685H | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as COSV54753026; called by muse, mutect2, varscan2
- RAD51AP2 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV67587992, COSV67588266; called by muse, mutect2, varscan2
- RAP1GDS1 | c.955C>G p.Q319E (on ENST00000408927 / NM_001100427.2; = p.Q320E on NM_021159.5) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV52788137; called by muse, mutect2, varscan2
- RBM28 | c.1931C>G p.S644C | Missense Mutation (SNP) | VAF 109/410 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV56163475; called by muse, mutect2, varscan2
- RBM47 | c.462C>G p.F154L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV55936769; called by muse, mutect2, varscan2
- RFX3 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV56517819; called by muse, mutect2, varscan2
- RGS14 | c.1004G>T p.R335L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.61); catalogued as COSV68771398; called by muse, mutect2, varscan2
- RIPK2 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55133673; called by muse, mutect2, varscan2
- RMC1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 87/577 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV52570863; called by muse, mutect2, varscan2
- RNF111 | c.2594C>G p.S865* | Nonsense Mutation (SNP) | VAF 70/281 reads (25%) | catalogued as COSV100789089; called by muse, mutect2, varscan2
- RNF149 | c.1032G>C p.L344F | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.708); catalogued as COSV54864360; called by muse, mutect2, varscan2
- RNF19A | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.037); catalogued as COSV61993609; called by muse, mutect2, varscan2
- RREB1 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV58561026, COSV58562521; called by muse, mutect2, varscan2
- RSF1 | c.4165G>A p.E1389K | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV57841352; called by muse, mutect2, varscan2
- RTP4 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV52018563; called by muse, mutect2, varscan2
- RUNDC1 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.631); catalogued as COSV100799323; called by muse, mutect2
- S1PR1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs756873576, COSV59513305; called by muse, mutect2
- SCAF11 | c.3812G>A p.S1271N | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV65477148; called by muse, mutect2, varscan2
- SCARF2 | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as COSV56731184; called by muse, mutect2, varscan2
- SCARF2 | c.656C>A p.S219* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99839337; called by muse, mutect2, varscan2
- SCN2A | c.5174A>G p.N1725S | Missense Mutation (SNP) | VAF 58/359 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51845168; called by muse, mutect2, varscan2
- SDHAF2 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57099458; called by muse, mutect2, varscan2
- SECISBP2 | c.390G>C p.E130D | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV60529033; called by muse, mutect2, varscan2
- SEMA3E | c.2209A>G p.R737G | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV57094594; called by muse, mutect2, varscan2
- SEMA3E | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV57094602, COSV57096944; called by muse, mutect2, varscan2
- SFI1 | c.3029G>A p.R1010Q (on ENST00000400288 / NM_001007467.3; = p.R979Q on NM_014775.4) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs756009048, COSV56717698; called by muse, mutect2, varscan2
- SH3BP4 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777420999, COSV60644357, COSV60645971; called by muse, mutect2, varscan2
- SH3D19 | c.1727G>A p.C576Y | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs557050445, COSV100455736, COSV58791201; called by muse, mutect2, varscan2
- SH3GL3 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1431662727, COSV61057873; called by muse, mutect2, varscan2
- SHANK1 | c.5582C>T p.S1861L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV53253264; called by muse, mutect2, varscan2
- SIGLEC10 | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.556); catalogued as COSV59482808; called by muse, mutect2, varscan2
- SIPA1L3 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs995224347, COSV55916572; called by muse, mutect2, varscan2
- SIVA1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as rs1425295583, COSV57331765; called by muse, mutect2, varscan2
- SLAIN2 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1560467821, COSV51907346; called by muse, mutect2, varscan2
- SLC12A5 | c.396G>T p.Q132H (on ENST00000454036 / NM_001134771.2; = p.Q109H on NM_020708.5) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54795359; called by muse, mutect2, varscan2
- SLC17A5 | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63287662; called by muse, mutect2, varscan2
- SLC22A9 | c.1074-1G>C p.X358_splice | Splice Site (SNP) | VAF 29/115 reads (25%) | catalogued as COSV54167693, COSV54167770; called by muse, mutect2, varscan2
- SLC27A2 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 123/401 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.262); catalogued as rs555678915, COSV51059785; called by muse, mutect2, varscan2
- SLC2A14 | c.1413C>A p.F471L | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV61587003; called by muse, mutect2, varscan2
- SLC35A4 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 71/232 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV60052052; called by muse, mutect2, varscan2
- SLC5A1 | c.1187C>A p.S396Y | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56686167; called by muse, mutect2, varscan2
- SLC6A1 | c.1374G>C p.M458I | Missense Mutation (SNP) | VAF 101/377 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV55116038; called by muse, mutect2, varscan2
- SLC6A2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54916415; called by muse, mutect2, varscan2
- SLC9C1 | c.1282C>G p.L428V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59889237; called by muse, mutect2, varscan2
- SLU7 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51788421; called by muse, mutect2, varscan2
- SMCO1 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58838308; called by muse, mutect2, varscan2
- SMG1 | c.7810C>G p.L2604V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV67172229; called by muse, mutect2, varscan2
- SMG1 | c.2260C>G p.L754V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.402); catalogued as COSV67172235; called by muse, mutect2, varscan2
- SNCAIP | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 86/311 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs147147229; called by muse, mutect2, varscan2
- SNX20 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100319231; called by muse, mutect2, varscan2
- SNX29 | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1170452948, COSV60062060; called by muse, mutect2
- SNX4 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); catalogued as COSV52538652; called by muse, mutect2
- SORCS3 | c.3226G>T p.D1076Y | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV63813405; called by muse, mutect2, varscan2
- SOX17 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as COSV52026350; called by muse, mutect2, varscan2
- SPATA31D1 | c.1747C>T p.Q583* | Nonsense Mutation (SNP) | VAF 52/118 reads (44%) | catalogued as COSV100782829, COSV61200381; called by muse, mutect2, varscan2
- SPTA1 | c.3960C>A p.D1320E | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV63754895; called by muse, mutect2, varscan2
- SPTBN1 | c.2198C>T p.S733L | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs1302344153, COSV61687598; called by muse, mutect2, varscan2
- SRSF8 | c.39G>A p.M13I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1163376734, COSV71665548; called by muse, mutect2, varscan2
- SSH3 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs78494651, COSV100354599, COSV57383865; called by muse, mutect2, varscan2
- SSRP1 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV53480020; called by muse, mutect2
- SSTR3 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.277); catalogued as rs143937169; called by muse, mutect2, varscan2
- ST3GAL5 | c.204C>G p.L68= | Splice Region (SNP) | VAF 62/198 reads (31%) | catalogued as COSV60386034; called by muse, mutect2, varscan2
- STS | c.1706G>A p.R569K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54269070; called by muse, mutect2, varscan2
- SUPT16H | c.2762G>A p.G921D | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52850105, COSV99251206; called by muse, mutect2, varscan2
- SUPT5H | c.2909C>T p.S970L | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV63240278; called by muse, mutect2, varscan2
- SYCP2 | c.3910G>A p.E1304K | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as rs201734541, COSV62769173; called by muse, mutect2, varscan2
- SYMPK | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); catalogued as COSV55612616; called by muse, mutect2, varscan2
- SYNE1 | c.9391C>G p.L3131V (on ENST00000367255 / NM_182961.4; = p.L3138V on NM_033071.3) | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.493); catalogued as COSV55009289; called by muse, mutect2, varscan2
- SYNJ1 | c.4124C>G p.S1375* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100449389; called by muse, mutect2, varscan2
- SYT4 | c.892C>A p.Q298K | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV54901369; called by muse, mutect2, varscan2
- TAS2R60 | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 77/342 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as COSV60331179; called by muse, mutect2, varscan2
- TASOR2 | c.4243C>T p.R1415* | Nonsense Mutation (SNP) | VAF 34/223 reads (15%) | catalogued as COSV60169291; called by muse, mutect2, varscan2
- TBC1D10C | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV56703304; called by muse, mutect2, varscan2
- TBC1D8B | c.3301G>C p.D1101H | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV52177368, COSV52179227; called by muse, mutect2, varscan2
- TBX2 | c.801G>C p.Q267H | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53599491; called by muse, mutect2, varscan2
- TBX2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53599502; called by muse, mutect2, varscan2
- TCF3 | c.1641G>C p.E547D | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV53649670; called by muse, mutect2, varscan2
- TCF3 | c.1306G>C p.G436R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV53649676, COSV99514572; called by muse, mutect2
- TECTB | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65595621; called by muse, mutect2, varscan2
- TENM1 | c.2903G>A p.R968K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV64434498; called by muse, mutect2, varscan2
- TENM2 | c.4750G>C p.E1584Q (on ENST00000518659 / NM_001122679.2; = p.E1345Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV69133153; called by muse, mutect2, varscan2
- TET1 | c.274C>G p.Q92E | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.108); catalogued as COSV65385678; called by muse, mutect2, varscan2
- TEX14 | c.1563G>C p.Q521H (on ENST00000240361 / NM_001201457.2; = p.Q515H on NM_031272.5) | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53619170, COSV53623896; called by muse, mutect2, varscan2
- TF | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV53921272; called by muse, mutect2, varscan2
- TG | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1330366991, COSV55076800; called by muse, mutect2, varscan2
- THBS1 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs982197700, COSV52952887; called by muse, mutect2, varscan2
- THOC2 | c.2609C>G p.S870C | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV55548533; called by muse, mutect2, varscan2
- THSD1 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51629271; called by muse, mutect2, varscan2
- TICRR | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.363); catalogued as rs766513294, COSV51542311; called by muse, mutect2, varscan2
- TJP2 | c.3027C>A p.F1009L | Missense Mutation (SNP) | VAF 128/325 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV55268611; called by muse, mutect2, varscan2
- TLN1 | c.2947C>T p.Q983* | Nonsense Mutation (SNP) | VAF 29/62 reads (47%) | catalogued as COSV100147847; called by muse, mutect2, varscan2
- TM9SF3 | c.1642C>G p.Q548E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64457657; called by muse, mutect2, varscan2
- TMEM131 | c.884T>G p.I295R | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51778102; called by muse, mutect2, varscan2
- TMEM143 | c.275C>G p.S92W | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs750428394, COSV53155415, COSV99507203; called by muse, mutect2, varscan2
- TMEM26 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99515657; called by muse, mutect2, varscan2
- TMX4 | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV55681077; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs762821746, COSV59528799; called by muse, mutect2, varscan2
- TOPBP1 | c.1563G>C p.L521F | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV53437046; called by muse, mutect2, varscan2
- TPBG | c.1205G>C p.R402T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63882313; called by muse, mutect2, varscan2
- TRAPPC2L | c.345C>G p.F115L | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV51938193; called by muse, mutect2, varscan2
- TRIM16 | c.1580C>G p.S527* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV100371954; called by muse, mutect2, varscan2
- TRIM8 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as COSV56660854; called by muse, mutect2, varscan2
- TRIOBP | c.5280C>G p.F1760L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.233); catalogued as COSV100730923; called by muse, mutect2, varscan2
- TRMU | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51990437; called by muse, mutect2, varscan2
- TRO | c.1463G>C p.R488P | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV51502808, COSV99435726; called by muse, mutect2, varscan2
- TRPM6 | c.3738C>G p.C1246W | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.438); catalogued as rs1416413858, COSV62513591; called by muse, mutect2, varscan2
- TRRAP | c.10228G>C p.D3410H (on ENST00000359863 / NM_001244580.1; = p.D3381H on NM_003496.3) | Missense Mutation (SNP) | VAF 96/323 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62846484; called by muse, mutect2, varscan2
- TTBK1 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as rs774742026, COSV52492567; called by muse, mutect2, varscan2
- TTC7A | c.2521G>T p.E841* | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | catalogued as COSV99766369; called by muse, mutect2, varscan2
- TTN | c.25078T>A p.Y8360N (on ENST00000591111; = p.Y7433N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/278 reads (32%) | PolyPhen benign (0.014); catalogued as COSV60129360; called by muse, mutect2, varscan2
- TUBB2A | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.305); catalogued as rs202207883, COSV61319193; called by muse, mutect2, varscan2
- TXNDC15 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as rs766474509, COSV100613582; called by muse, mutect2, varscan2
- UBASH3B | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 112/351 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV52496487; called by muse, mutect2, varscan2
- UBR4 | c.7516C>G p.Q2506E | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV64391812; called by muse, mutect2, varscan2
- UQCRC2 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs772845666, COSV51672562; called by muse, mutect2, varscan2
- URB2 | c.3550C>G p.L1184V | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV50997158, COSV99270843; called by muse, mutect2, varscan2
- USE1 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs767863073, COSV55728062; called by muse, mutect2, varscan2
- USP32 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV56266464, COSV56270517; called by muse, mutect2, varscan2
- USP48 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV57607106; called by muse, mutect2, varscan2
- VPS13A | c.5383G>T p.E1795* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100652971; called by muse, mutect2, varscan2
- VPS39 | c.345G>C p.K115N (on ENST00000348544 / NM_001301138.2; = p.K104N on NM_015289.5) | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58790279; called by muse, mutect2, varscan2
- WBP11 | c.526C>G p.P176A | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV53763343; called by muse, mutect2, varscan2
- WDFY3 | c.10363G>A p.E3455K | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV55693763; called by muse, mutect2, varscan2
- WDFY3 | c.10117G>T p.E3373* | Nonsense Mutation (SNP) | VAF 22/176 reads (13%) | catalogued as COSV99883944; called by muse, varscan2
- WDR11 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as COSV54789436; called by muse, mutect2, varscan2
- WDR20 | c.302C>G p.P101R | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54473026; called by muse, mutect2, varscan2
- WDR93 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1285694676, COSV51533018; called by muse, mutect2, varscan2
- WNT7A | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs760828095, COSV53199705; called by muse, mutect2, varscan2
- XKR9 | c.110A>G p.Q37R | Missense Mutation (SNP) | VAF 95/349 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV68773076; called by muse, mutect2, varscan2
- ZAN | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV61810465; called by muse, mutect2, varscan2
- ZBTB11 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV57245499; called by muse, mutect2, varscan2
- ZBTB22 | c.1240C>G p.R414G | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as rs763905341, COSV56466868, COSV56470411; called by muse, mutect2, varscan2
- ZCCHC2 | c.1761T>G p.I587M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV54038702; called by muse, mutect2, varscan2
- ZDHHC8 | c.1517C>G p.S506* | Nonsense Mutation (SNP) | VAF 44/162 reads (27%) | catalogued as COSV100272933; called by muse, mutect2, varscan2
- ZHX2 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV58714113, COSV99041881; called by muse, mutect2, varscan2
- ZMYND12 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as rs376308865; called by muse, mutect2, varscan2
- ZNF160 | c.706C>G p.H236D | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1054097652, COSV62000014, COSV62000935; called by muse, mutect2, varscan2
- ZNF236 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as COSV53490453; called by muse, mutect2, varscan2
- ZNF254 | c.1702C>T p.H568Y | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV61643060; called by muse, mutect2, varscan2
- ZNF347 | c.1626G>T p.M542I | Missense Mutation (SNP) | VAF 81/272 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV61969207; called by muse, mutect2, varscan2
- ZNF423 | c.192G>C p.E64D (on ENST00000563137 / NM_001379286.1; = p.E56D on NM_015069.4) | Missense Mutation (SNP) | VAF 73/381 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV52193088; called by muse, mutect2, varscan2
- ZNF432 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1242506249, COSV55417138; called by muse, mutect2, varscan2
- ZNF485 | c.680C>G p.S227* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV62424034; called by muse, mutect2, varscan2
- ZNF516 | c.2989C>G p.L997V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs780700103, COSV71586883; called by muse, mutect2, varscan2
- ZNF543 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV58627886; called by muse, varscan2
- ZNF543 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1235212307, COSV58627895; called by muse, varscan2
- ZNF644 | c.3325C>G p.Q1109E | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as COSV61348333; called by muse, mutect2, varscan2
- ZNF675 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 35/121 reads (29%) | catalogued as COSV100705082; called by muse, mutect2, varscan2
- ZNF676 | c.1142C>A p.S381Y (on ENST00000650058; = p.S349Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.734); catalogued as rs1177440390, COSV68093179, COSV68093445; called by muse, mutect2, varscan2
- ZNF677 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61720529; called by muse, mutect2, varscan2
- ZNF786 | c.1386C>A p.F462L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs781760625, COSV60276586, COSV60277627; called by muse, mutect2, varscan2
- ZNF827 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs147914934; called by muse, mutect2, varscan2
- ZSCAN5B | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | catalogued as COSV100627991; called by muse, mutect2, varscan2
- ZSCAN5B | c.987C>G p.I329M | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs755476251, COSV62000390; called by muse, mutect2, varscan2
- DMD | c.1206_1207delinsT p.L402Ffs*5 | Frame Shift Del (DEL) | VAF 34/98 reads (35%) | called by pindel, varscan2*
- DNAH8 | c.2012del p.K671Rfs*6 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HDGF | c.230del p.N77Tfs*78 | Frame Shift Del (DEL) | VAF 32/115 reads (28%) | called by mutect2, pindel, varscan2
- POPDC3 | c.763del p.R255Dfs*24 | Frame Shift Del (DEL) | VAF 48/142 reads (34%) | called by mutect2, varscan2
- PPFIA1 | c.3547_3550+5del p.X1183_splice | Splice Site (DEL) | VAF 31/138 reads (22%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1891C>G p.P631A | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.618); called by mutect2, varscan2
- ABCA4 | c.3822G>A p.L1274= | Silent (SNP) | VAF 40/225 reads (18%) | catalogued as rs142715811, COSV64674398; called by muse, mutect2, varscan2
- ACHE | c.990C>T p.F330= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV53815366; called by muse, mutect2, varscan2
- AMBRA1 | c.1731C>T p.F577= (on ENST00000458649 / NM_001367468.1; = p.F487= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as COSV54056521; called by muse, mutect2, varscan2
- ANKRD34B | c.264G>C p.L88= | Silent (SNP) | VAF 80/284 reads (28%) | catalogued as COSV58614077; called by muse, mutect2, varscan2
- ARFGEF2 | c.1881G>A p.Q627= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV64212937; called by muse, mutect2, varscan2
- ARHGAP26 | c.1641C>A p.I547= | Silent (SNP) | VAF 49/168 reads (29%) | catalogued as COSV50832011, COSV50832662, COSV50836679; called by muse, mutect2, varscan2
- ARID3C | c.1122C>T p.N374= | Silent (SNP) | VAF 61/164 reads (37%) | catalogued as rs563083593, COSV52406973; called by muse, mutect2, varscan2
- ASIC2 | c.789G>T p.G263= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV56764303; called by muse, mutect2, varscan2
- ATRIP | c.1902G>C p.L634= | Silent (SNP) | VAF 105/318 reads (33%) | catalogued as COSV56497191; called by muse, mutect2, varscan2
- B4GALT4 | c.159G>A p.K53= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV63295965; called by muse, mutect2, varscan2
- BAHCC1 | c.4419G>A p.E1473= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs1224430207, COSV57028112; called by muse, mutect2, varscan2
- BOK | c.537C>A p.V179= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV59192117, COSV59192650; called by muse, mutect2, varscan2
- BRCA2 | c.513G>A p.V171= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV66452771, COSV66455475; called by muse, mutect2, varscan2
- BRD2 | c.120T>C p.Y40= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as rs148450256; called by muse, mutect2, varscan2
- BTN3A2 | c.663C>T p.I221= | Silent (SNP) | VAF 49/245 reads (20%) | catalogued as COSV62687481; called by muse, mutect2, varscan2
- C16orf89 | c.849A>G p.E283= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV60124326; called by muse, mutect2, varscan2
- C16orf89 | c.276G>C p.V92= | Silent (SNP) | VAF 57/186 reads (31%) | catalogued as rs1346918796, COSV60124355, COSV60124722; called by muse, mutect2, varscan2
- C21orf62 | c.18G>A p.R6= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV66672194; called by muse, mutect2, varscan2
- CADPS | c.804G>A p.L268= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV51885147; called by muse, mutect2, varscan2
- CAMSAP2 | c.2434C>T p.L812= (on ENST00000236925 / NM_001297707.2; = p.L801= on NM_203459.3) | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as rs1472339340, COSV52672422; called by muse, mutect2, varscan2
- CANX | c.789C>G p.L263= | Silent (SNP) | VAF 58/193 reads (30%) | catalogued as COSV56004732; called by muse, mutect2, varscan2
- CAV3 | c.429C>T p.I143= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as COSV57479642; called by muse, mutect2, varscan2
- CCDC198 | c.696G>A p.V232= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV53602405; called by muse, mutect2, varscan2
- CDC42EP4 | c.498G>T p.R166= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV59963164; called by muse, mutect2, varscan2
- CDCP2 | c.555G>A p.L185= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs765203888, COSV61284248; called by muse, mutect2, varscan2
- CDH8 | c.1842C>T p.V614= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as rs772027090, COSV54873703; called by muse, mutect2, varscan2
- CDK5R1 | c.354G>A p.Q118= | Silent (SNP) | VAF 27/191 reads (14%) | catalogued as COSV55579333; called by muse, varscan2
- CEP85 | c.1512G>A p.L504= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV53330122; called by muse, mutect2, varscan2
- CFAP298 | c.726G>C p.L242= | Silent (SNP) | VAF 8/154 reads (5%) | catalogued as COSV51592427, COSV51592894; called by muse, mutect2
- CHD7 | c.8448G>A p.L2816= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV71111945; called by muse, mutect2, varscan2
- CLSTN1 | c.378C>T p.F126= (on ENST00000377298 / NM_001009566.3; = p.F116= on NM_014944.4) | Silent (SNP) | VAF 70/273 reads (26%) | catalogued as COSV63648672; called by muse, mutect2, varscan2
- CMIP | c.1377C>T p.I459= (on ENST00000537098 / NM_198390.2; = p.I365= on NM_030629.3) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1449221924, COSV67698803; called by muse, mutect2, varscan2
- COL19A1 | c.9C>T p.L3= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV59576217; called by muse, mutect2, varscan2
- COL5A1 | c.2181C>T p.G727= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs201298716, COSV65667559; called by muse, mutect2, varscan2
- COL6A6 | c.4626C>A p.P1542= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV62024703, COSV62027955; called by muse, mutect2, varscan2
- CTNNA3 | c.1077G>A p.L359= | Silent (SNP) | VAF 27/203 reads (13%) | catalogued as COSV65593132; called by muse, mutect2, varscan2
- CUBN | c.6516T>C p.N2172= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV64718452; called by muse, mutect2, varscan2
- CUL2 | c.1254C>T p.F418= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV66079490; called by muse, mutect2, varscan2
- DCSTAMP | c.510C>A p.T170= | Silent (SNP) | VAF 41/232 reads (18%) | catalogued as rs765227158, COSV52577620; called by muse, mutect2, varscan2
- DHX57 | c.3624G>A p.E1208= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV54886555; called by muse, mutect2, varscan2
- DLG5 | c.4932G>A p.Q1644= | Silent (SNP) | VAF 68/198 reads (34%) | catalogued as rs1342191667, COSV64948456; called by muse, mutect2, varscan2
- DMGDH | c.666G>A p.L222= | Silent (SNP) | VAF 95/357 reads (27%) | catalogued as rs267600702, COSV54865045; called by muse, mutect2, varscan2
- DNAH11 | c.3072C>T p.I1024= | Silent (SNP) | VAF 92/329 reads (28%) | catalogued as COSV60960977; called by muse, mutect2, varscan2
- DNAJC6 | c.2115G>A p.P705= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs367640667; called by muse, mutect2, varscan2
- DOP1B | c.1608C>T p.L536= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV101215501; called by muse, mutect2
- DSCAM | c.2163C>A p.I721= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV68029038; called by muse, mutect2, varscan2
- DXO | c.21G>A p.K7= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV61713977; called by muse, mutect2, varscan2
- EIF4G3 | c.4515G>A p.E1505= | Silent (SNP) | VAF 28/160 reads (18%) | catalogued as rs765327468, COSV51684992; called by muse, mutect2, varscan2
- EN1 | c.379C>T p.L127= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV54631638; called by muse, mutect2
- ERICH3 | c.2985C>T p.S995= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs1408259682, COSV58609631; called by muse, mutect2, varscan2
- ESYT3 | c.1419C>T p.L473= | Silent (SNP) | VAF 112/443 reads (25%) | catalogued as rs757531421, COSV67441196; called by muse, mutect2, varscan2
- ETNK2 | c.987C>G p.L329= | Silent (SNP) | VAF 37/197 reads (19%) | catalogued as COSV65819919; called by muse, mutect2, varscan2
- FAM135A | c.4533C>G p.L1511= (on ENST00000370479 / NM_001351599.1; = p.L1298= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1331335469, COSV99525945; called by muse, mutect2
- FAM234B | c.294G>A p.L98= | Silent (SNP) | VAF 30/198 reads (15%) | catalogued as rs1473666675, COSV52195209; called by muse, varscan2
- FBH1 | c.1884G>A p.L628= (on ENST00000362091 / NM_178150.3; = p.L679= on NM_032807.4) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV62983028; called by muse, mutect2, varscan2
- FBXO21 | c.1074G>A p.L358= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as COSV57973334; called by muse, mutect2, varscan2
- FCSK | c.1875G>A p.R625= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99850964; called by muse, mutect2
- FHOD3 | c.1576C>T p.L526= (on ENST00000359247 / NM_001281739.3; = p.L543= on NM_025135.5) | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV57176334; called by muse, mutect2, varscan2
- FOXK2 | c.1176C>T p.S392= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1242327539, COSV58879801; called by muse, mutect2, varscan2
- GANC | c.2034A>G p.P678= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as rs1487628959, COSV58809526; called by muse, mutect2, varscan2
- GFRA3 | c.483C>G p.L161= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV51229068; called by muse, mutect2, varscan2
- GJB4 | c.243C>T p.L81= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV58356415; called by muse, mutect2, varscan2
- GLO1 | c.333G>A p.E111= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as rs749648363, COSV64905151; called by muse, varscan2
- GLUD1 | c.267G>A p.L89= | Silent (SNP) | VAF 76/240 reads (32%) | catalogued as COSV53278328, COSV53279093; called by muse, mutect2, varscan2
- GOLGA4 | c.1899C>G p.V633= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs778402708, COSV62711413; called by muse, mutect2, varscan2
- GPR27 | c.1110G>C p.L370= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99816504; called by muse, mutect2, varscan2
- GPR78 | c.834C>T p.L278= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs1471938389, COSV101224014, COSV66763259; called by muse, mutect2, varscan2
- GRWD1 | c.1251G>A p.L417= | Silent (SNP) | VAF 70/213 reads (33%) | catalogued as COSV53519160; called by muse, mutect2, varscan2
- GSDME | c.1164C>T p.F388= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV61651333, COSV61651996; called by muse, mutect2, varscan2
- H2AW | c.168C>T p.L56= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV64209865; called by muse, mutect2, varscan2
- HACL1 | c.1059G>A p.L353= | Silent (SNP) | VAF 42/187 reads (22%) | catalogued as COSV58254936; called by muse, mutect2, varscan2
- HECTD4 | c.11973G>A p.L3991= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs1296700390, COSV66393777; called by muse, mutect2, varscan2
- HECW1 | c.1632G>A p.T544= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as rs768142577, COSV101224174, COSV67830395; called by muse, mutect2, varscan2
- HERC2 | c.11334G>A p.L3778= | Silent (SNP) | VAF 65/197 reads (33%) | catalogued as COSV55328691; called by muse, mutect2, varscan2
- HIC2 | c.324C>T p.S108= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs191884142, COSV68042314; called by muse, mutect2, varscan2
- HRNR | c.3114C>T p.G1038= | Silent (SNP) | VAF 124/421 reads (29%) | catalogued as rs561488430, COSV64259197; called by muse, mutect2, varscan2
- IFT122 | c.2958C>T p.P986= (on ENST00000348417 / NM_052989.3; = p.P927= on NM_018262.4) | Silent (SNP) | VAF 99/329 reads (30%) | catalogued as COSV56204197; called by muse, mutect2, varscan2
- IFT81 | c.30C>T p.D10= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV54363452; called by muse, mutect2, varscan2
- IGHG4 | c.639G>A p.E213= | Silent (SNP) | VAF 202/743 reads (27%) | catalogued as rs748523196; called by muse, mutect2, varscan2
- IGKV6-21 | c.327G>A p.Q109= | Silent (SNP) | VAF 40/230 reads (17%) | catalogued as rs748215638; called by muse, varscan2
- INPP5F | c.2277C>T p.I759= | Silent (SNP) | VAF 57/193 reads (30%) | catalogued as COSV62821514; called by muse, mutect2, varscan2
- ISL1 | c.441C>T p.L147= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV57934202; called by muse, mutect2, varscan2
- ISOC2 | c.549C>T p.L183= (on ENST00000425675 / NM_001136201.2; = p.L199= on NM_024710.3) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV50035073; called by muse, mutect2, varscan2
- IVD | c.31C>T p.L11= (on ENST00000651168; = p.L8= on NM_002225.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as rs773816252, COSV51099537, COSV99991451; ClinVar: likely benign; called by muse, mutect2, varscan2
- JMJD4 | c.132G>C p.L44= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100248249; called by muse, mutect2
- KATNIP | c.1596G>A p.R532= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV55183188; called by muse, mutect2, varscan2
- KCNB2 | c.2652G>A p.K884= | Silent (SNP) | VAF 51/187 reads (27%) | catalogued as COSV73050869; called by muse, mutect2, varscan2
- KIAA2026 | c.3507C>T p.F1169= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV67355813; called by muse, mutect2, varscan2
- KMT2D | c.3861G>A p.E1287= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV56451776; called by muse, mutect2, varscan2
- KNTC1 | c.1518C>T p.L506= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV61080812; called by muse, mutect2, varscan2
- KRTAP4-1 | c.174T>C p.T58= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV66648674; called by muse, mutect2, varscan2
- LAG3 | c.1215C>G p.L405= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as COSV52567861; called by muse, mutect2, varscan2
- LETM1 | c.810G>A p.E270= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as rs1443417814, COSV57101856; called by muse, mutect2, varscan2
- LILRB4 | c.1233G>A p.V411= (on ENST00000391733 / NM_001278428.3; = p.V410= on NM_001278426.3) | Silent (SNP) | VAF 56/181 reads (31%) | catalogued as COSV54406189; called by muse, mutect2, varscan2
- LIPF | c.942T>C p.N314= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs767280430, COSV53284563; called by muse, mutect2, varscan2
- LLGL1 | c.153C>T p.I51= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as rs145857913; called by muse, mutect2, varscan2
- LRATD1 | c.843C>G p.L281= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV54473149; called by muse, mutect2, varscan2
- LRRC37A3 | c.42C>T p.S14= | Silent (SNP) | VAF 39/345 reads (11%) | catalogued as COSV59761973; called by muse, mutect2, varscan2
- MAP3K19 | c.465G>A p.V155= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV59639653; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3612C>T p.I1204= | Silent (SNP) | VAF 95/305 reads (31%) | catalogued as COSV51601157; called by muse, mutect2, varscan2
- MASP1 | c.1119G>A p.L373= | Silent (SNP) | VAF 54/200 reads (27%) | catalogued as COSV51460626; called by muse, mutect2, varscan2
- MBD4 | c.732G>A p.K244= | Silent (SNP) | VAF 66/269 reads (25%) | catalogued as COSV51444866; called by muse, mutect2, varscan2
- MCOLN1 | c.981G>A p.Q327= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV51176653; called by muse, mutect2, varscan2
- METTL18 | c.873C>T p.L291= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99609900; called by muse, mutect2, varscan2
- MFSD2B | c.303C>T p.F101= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV100601079; called by muse, mutect2
- MKX | c.324C>T p.L108= | Silent (SNP) | VAF 82/233 reads (35%) | catalogued as COSV65392391; called by muse, mutect2, varscan2
- MLXIPL | c.36G>A p.L12= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100515400; called by muse, mutect2, varscan2
- MPPE1 | c.712C>T p.L238= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV57882839; called by muse, mutect2, varscan2
- MPST | c.699C>T p.F233= (on ENST00000341116 / NM_001369904.2; = p.F253= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV62017813; called by muse, mutect2, varscan2
- MRC2 | c.690C>T p.I230= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV57640787; called by muse, mutect2, varscan2
- MSTO1 | c.822G>A p.Q274= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as COSV55472287; called by muse, mutect2, varscan2
- MTSS2 | c.693G>A p.L231= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs762888112, COSV58698486, COSV58698642; called by muse, mutect2, varscan2
- MXRA5 | c.6444C>T p.I2148= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV54238750; called by muse, mutect2, varscan2
- MYH11 | c.3765G>A p.K1255= | Silent (SNP) | VAF 119/458 reads (26%) | catalogued as COSV55556769; called by muse, mutect2, varscan2
- N4BP2 | c.2589C>A p.L863= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs761974212, COSV54703117; called by muse, mutect2, varscan2
- NCSTN | c.2040C>T p.L680= | Silent (SNP) | VAF 102/377 reads (27%) | catalogued as rs1470723159, COSV54188384; called by muse, mutect2, varscan2
- NDST2 | c.432C>T p.L144= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as rs1222925071, COSV55215582, COSV55217825; called by muse, mutect2, varscan2
- NLRP1 | c.1266G>A p.P422= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs766952690, COSV52568708; called by muse, mutect2, varscan2
- NPAT | c.2220C>G p.L740= | Silent (SNP) | VAF 38/169 reads (22%) | catalogued as COSV53718766; called by muse, mutect2, varscan2
- NUP205 | c.4620C>A p.L1540= | Silent (SNP) | VAF 47/184 reads (26%) | catalogued as COSV53660772; called by muse, mutect2, varscan2
- NUP205 | c.5781G>A p.S1927= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as rs773758194, COSV53660795; called by muse, varscan2
- OR10K2 | c.81C>G p.L27= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV59221531; called by muse, mutect2, varscan2
- OR10P1 | c.921G>A p.K307= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs1415974962, COSV100548127, COSV100548181; called by muse, mutect2
- OR14I1 | c.12C>G p.L4= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV61200063; called by muse, mutect2, varscan2
- OR2T6 | c.765C>A p.A255= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV63216529; called by muse, mutect2, varscan2
- OR6V1 | c.825G>A p.V275= | Silent (SNP) | VAF 9/152 reads (6%) | catalogued as COSV69237380; called by muse, mutect2
- PAMR1 | c.159C>T p.C53= | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as rs1162976422, COSV53512371; called by muse, mutect2, varscan2
- PARP15 | c.1938C>G p.L646= (on ENST00000464300 / NM_001113523.3; = p.L412= on NM_152615.2) | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV100117000, COSV59973078; called by muse, mutect2, varscan2
- PCCB | c.210C>A p.I70= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as COSV52445776, COSV52446002; called by muse, mutect2, varscan2
- PCDHB16 | c.2058C>G p.L686= | Silent (SNP) | VAF 79/142 reads (56%) | catalogued as COSV53364093; called by muse, mutect2, varscan2
- PIP5KL1 | c.624C>T p.F208= (on ENST00000388747 / NM_001135219.2; = p.F5= on NM_173492.1) | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV55944755; called by muse, mutect2, varscan2
- PKHD1 | c.10581G>A p.L3527= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV64392405; called by muse, mutect2, varscan2
- PLEKHM1 | c.513C>G p.L171= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV69599064; called by muse, mutect2, varscan2
- PLIN3 | c.342G>T p.T114= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as COSV55735663; called by muse, mutect2, varscan2
- PLPP1 | c.591C>G p.L197= | Silent (SNP) | VAF 48/160 reads (30%) | catalogued as COSV53303921; called by muse, mutect2, varscan2
- PLXNA4 | c.3813G>A p.L1271= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as rs994766263, COSV58134050; called by muse, mutect2, varscan2
- PPCS | c.78C>T p.F26= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1163785310, COSV65333686; called by mutect2, varscan2
- PPP1R14D | c.393C>T p.L131= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs140774733; called by muse, mutect2, varscan2
- PRAMEF12 | c.711C>G p.L237= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as COSV63215598; called by muse, varscan2
- PRG2 | c.351G>C p.T117= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV61293688; called by muse, mutect2, varscan2
- PRKCA | c.1500G>A p.G500= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs1331734907, COSV52587376; called by muse, mutect2, varscan2
- PRMT6 | c.192C>T p.R64= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs748458420, COSV63655712; called by muse, mutect2, varscan2
- PRSS36 | c.306G>C p.S102= | Silent (SNP) | VAF 46/165 reads (28%) | catalogued as rs764003560, COSV51637946; called by muse, mutect2, varscan2
- RAPGEF6 | c.2229C>G p.S743= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV57248412; called by muse, mutect2, varscan2
- RBM38 | c.468G>A p.V156= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV61134396; called by muse, mutect2, varscan2
- RDH16 | c.900C>T p.F300= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV62458290; called by muse, mutect2, varscan2
- RELN | c.9468G>A p.Q3156= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs1340943020, COSV59009327; ClinVar: likely benign; called by muse, mutect2, varscan2
- RFX4 | c.39C>A p.S13= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV67273301; called by muse, mutect2, varscan2
- RGS12 | c.3063C>T p.I1021= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV58749529, COSV58753264; called by muse, varscan2
- RHCE | c.684G>T p.L228= | Silent (SNP) | VAF 120/285 reads (42%) | catalogued as COSV53801188; called by muse, mutect2
- RNLS | c.612G>A p.T204= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as rs780650761, COSV59293079; called by muse, mutect2, varscan2
- ROBO4 | c.1632C>T p.L544= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV60625107; called by muse, mutect2, varscan2
- S1PR4 | c.666C>G p.L222= | Silent (SNP) | VAF 100/403 reads (25%) | catalogued as COSV55740525, COSV55741115; called by muse, mutect2, varscan2
- SACS | c.7497C>A p.V2499= | Silent (SNP) | VAF 46/188 reads (24%) | catalogued as COSV66541599; called by muse, mutect2, varscan2
- SDHD | c.363G>A p.Q121= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV65019503; called by muse, mutect2, varscan2
- SELENOT | c.21C>G p.L7= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs750653580, COSV72000499; called by muse, varscan2
- SEMA3A | c.1746G>A p.E582= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV54874350, COSV99544653; called by muse, mutect2, varscan2
- SGIP1 | c.1164C>T p.F388= | Silent (SNP) | VAF 58/219 reads (26%) | catalogued as COSV52771478; called by muse, mutect2, varscan2
- SHANK3 | c.1950C>T p.L650= | Silent (SNP) | VAF 54/142 reads (38%) | catalogued as rs774896173, COSV53187530; called by muse, mutect2, varscan2
- SI | c.2388C>T p.I796= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV52269258; called by muse, mutect2, varscan2
- SLC20A2 | c.696C>G p.L232= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as COSV60604331; called by muse, mutect2, varscan2
- SLC26A4 | c.1411C>T p.L471= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as rs1224848656, COSV55917378; called by muse, mutect2, varscan2
- SLC32A1 | c.1416G>A p.L472= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs1421240924, COSV54147137; called by muse, mutect2, varscan2
- SLC35B2 | c.180C>T p.F60= | Silent (SNP) | VAF 108/374 reads (29%) | catalogued as COSV51490031, COSV99241037; called by muse, mutect2, varscan2
- SLC4A11 | c.525C>G p.L175= | Silent (SNP) | VAF 78/253 reads (31%) | catalogued as COSV66262359, COSV66264330; called by muse, mutect2, varscan2
- SLCO1B3 | c.1245G>C p.S415= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV53939736, COSV53940841; called by muse, mutect2, varscan2
- SMAD3 | c.831C>G p.V277= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV59285178; called by muse, mutect2, varscan2
- SMAD6 | c.1356C>T p.P452= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as rs1266588396, COSV56595539; called by muse, mutect2, varscan2
- SOCS7 | c.1434G>A p.L478= | Silent (SNP) | VAF 33/101 reads (33%) | called by muse, mutect2, varscan2
- SPAG1 | c.1929C>T p.L643= | Silent (SNP) | VAF 90/250 reads (36%) | catalogued as COSV52560516; called by muse, mutect2, varscan2
- SSRP1 | c.1542G>A p.E514= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as COSV53480010; called by muse, mutect2
- STK19 | c.120C>T p.T40= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as COSV61713989; called by muse, varscan2
- STK36 | c.600C>T p.F200= | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as COSV55308061; called by muse, mutect2, varscan2
- STMN2 | c.60G>A p.L20= | Silent (SNP) | VAF 41/158 reads (26%) | catalogued as rs1182475781, COSV55220173; called by muse, mutect2, varscan2
- TAGAP | c.1311G>A p.P437= | Silent (SNP) | VAF 77/168 reads (46%) | catalogued as rs376291466; called by muse, mutect2, varscan2
- TBKBP1 | c.1764C>A p.L588= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV64653854; called by muse, mutect2, varscan2
- TCHHL1 | c.27C>G p.L9= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as COSV100916555, COSV64286122; called by muse, mutect2, varscan2
- THSD7A | c.651G>C p.R217= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV70266490; called by muse, mutect2, varscan2
- TINF2 | c.430C>T p.L144= | Silent (SNP) | VAF 84/254 reads (33%) | catalogued as COSV57469340; called by muse, mutect2, varscan2
- TMEM170A | c.264G>A p.L88= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs139740117; called by muse, mutect2, varscan2
- TRANK1 | c.3564C>T p.L1188= | Silent (SNP) | VAF 90/387 reads (23%) | catalogued as rs149155370, COSV57153457; called by muse, mutect2, varscan2
- TRPC6 | c.2181C>T p.I727= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as rs1220200421, COSV60256316; called by muse, mutect2, varscan2
- TTLL4 | c.3303G>C p.V1101= | Silent (SNP) | VAF 64/323 reads (20%) | catalogued as COSV51436990; called by muse, mutect2, varscan2
- TULP2 | c.657G>A p.K219= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV55476794; called by muse, mutect2, varscan2
- TXNIP | c.996C>G p.P332= | Silent (SNP) | VAF 31/207 reads (15%) | catalogued as COSV65220371, COSV65220693; called by muse, mutect2, varscan2
- ULK4 | c.1413G>A p.Q471= | Silent (SNP) | VAF 53/198 reads (27%) | catalogued as COSV57212122; called by muse, mutect2, varscan2
- UNC13D | c.42C>T p.F14= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs776563028, COSV52883410; called by muse, mutect2, varscan2
- VIL1 | c.759C>G p.L253= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV50289806; called by muse, mutect2
- VSIG1 | c.24C>G p.V8= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV54259832; called by muse, mutect2, varscan2
- ZBTB48 | c.567C>T p.L189= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as COSV59840041; called by muse, mutect2, varscan2
- ZDHHC5 | c.2076C>T p.L692= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs746536011, COSV54707340; called by muse, mutect2, varscan2
- ZNF479 | c.936C>T p.L312= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV58641621; called by muse, mutect2, varscan2
- ZNHIT3 | c.330C>T p.L110= | Silent (SNP) | VAF 24/192 reads (13%) | called by muse, mutect2, varscan2
- AL162417.1 | c.397-17010C>G | Intron (SNP) | VAF 13/40 reads (33%) | catalogued as COSV64454486; called by muse, mutect2, varscan2
- BICD2 | c.2469+9C>T | Intron (SNP) | VAF 27/69 reads (39%) | catalogued as rs567357617, COSV63549370; called by muse, mutect2, varscan2
- CANT1 | c.*826G>A | 3'UTR (SNP) | VAF 14/45 reads (31%) | catalogued as rs1233892453, COSV100185300; called by muse, mutect2, varscan2
- CAPRIN2 | c.2148+1617C>A | Intron (SNP) | VAF 44/205 reads (21%) | catalogued as rs753175399, COSV99195529; called by muse, mutect2, varscan2
- CDC42 | c.487-1399C>T | Intron (SNP) | VAF 13/38 reads (34%) | catalogued as COSV59662474; called by muse, mutect2, varscan2
- CPLANE1 | c.7957+284G>C | Intron (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- DLG4 | chr17:7218273 C>A | 5'Flank (SNP) | VAF 11/23 reads (48%) | catalogued as rs951378823, COSV57239417; called by muse, mutect2, varscan2
- DMRT2 | c.629-447C>G | Intron (SNP) | VAF 13/68 reads (19%) | catalogued as COSV52402208; called by muse, mutect2, varscan2
- FHL2 | c.-76+61C>T | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as rs1447935379, COSV59079765; called by muse, mutect2, varscan2
- FMN1 | c.2044-1511G>A | Intron (SNP) | VAF 16/54 reads (30%) | catalogued as COSV57925102; called by muse, mutect2, varscan2
- GFOD1 | c.253+16388G>C | Intron (SNP) | VAF 8/41 reads (20%) | catalogued as COSV64953238; called by muse, mutect2, varscan2
- KCNIP2 | c.765+18C>G | Intron (SNP) | VAF 10/64 reads (16%) | catalogued as COSV53307575; called by muse, mutect2, varscan2
- LARP7 | c.1142+564C>T | Intron (SNP) | VAF 35/123 reads (28%) | catalogued as rs756098665, COSV60521779; called by muse, mutect2, varscan2
- LBX2 | chr2:74502860 C>G | 5'Flank (SNP) | VAF 19/86 reads (22%) | catalogued as COSV99283349; called by muse, mutect2, varscan2
- MAGEC3 | c.1729-34C>A | Intron (SNP) | VAF 30/70 reads (43%) | catalogued as COSV53581800; called by muse, mutect2, varscan2
12 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 12 other) are not listed here.
